Somatic mutation profile of tumor specimen TARGET-10-PARGBK-09A (aliquot TARGET-10-PARGBK-09A-01D) from TARGET case TARGET-10-PARGBK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.3 years (4,850 days).
Specimen TARGET-10-PARGBK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf454901-1d82-4448-b4c2-bbff84f0e5ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGBK-14A (Bone Marrow Normal), aliquot TARGET-10-PARGBK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3feb07c6-8659-4cf8-b63c-66d79295785e

The open-access MAF lists 40 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Intron 4, 3'UTR 3, Nonsense Mutation 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF1A | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548204329; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2
- ACTN3 | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs758580966, COSV59750770, COSV59750906; called by muse, mutect2, varscan2
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 47/150 reads (31%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- ATR | c.3244C>T p.R1082C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1449808108; called by muse, mutect2, varscan2
- GREB1L | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs559234950; called by muse, mutect2, varscan2
- LIPE | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.667); catalogued as rs770082597; called by muse, mutect2, varscan2
- MET | c.2960G>A p.R987Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs910937816, COSV59263954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OOEP | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1031891996, COSV64859430; called by muse, mutect2, varscan2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2, varscan2
- RNF133 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs140329176; called by muse, mutect2, varscan2
- SCNN1D | c.566G>A p.R189Q (on ENST00000338555; = p.R353Q on NM_001130413.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.595); catalogued as rs760368506, COSV100329841; called by muse, mutect2, varscan2
- TMEM132D | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs143170493; called by muse, mutect2, varscan2
- CAD | c.5165G>T p.R1722L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUOXA2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HFM1 | c.1778C>A p.S593* | Nonsense Mutation (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- HPGDS | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INO80 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPN11 | c.311G>C p.C104S | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.071); called by muse, mutect2
- SNAI2 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTYH2 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- APC2 | c.3783G>A p.V1261= | Silent (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- ATP1A2 | c.1317C>T p.S439= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs759939624, COSV63405341; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CHD7 | c.2397C>T p.G799= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs991449261; called by muse, mutect2, varscan2
- DIP2A | c.4584C>T p.V1528= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs749118833; called by muse, mutect2, varscan2
- DST | c.15117G>A p.L5039= (on ENST00000361203 / NM_001374722.1; = p.L2627= on NM_015548.5) | Silent (SNP) | VAF 56/215 reads (26%) | called by muse, mutect2, varscan2
- FLCN | c.318C>T p.Y106= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs773946854, COSV53260653; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCARE | c.2196G>A p.K732= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- RET | c.1098G>A p.E366= | Silent (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- UGT1A4 | c.273C>T p.R91= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs777889736, COSV59401720; called by muse, mutect2, varscan2
- AC007546.3 | n.75G>C | RNA (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- CASTOR2 | c.*3960C>T | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- CSF1R | c.*65G>A | 3'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as rs1322716836; called by muse, mutect2, varscan2
- EYS | c.1767-6607C>T | Intron (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- EYS | c.1767-7273T>C | Intron (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- NDUFS2 | c.1354+46C>T | Intron (SNP) | VAF 7/53 reads (13%) | catalogued as rs1049281061, COSV57155233, COSV57155662; called by muse, mutect2, varscan2
- SLC25A26 | chr3:66220989 G>A | 5'Flank (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- WSCD1 | c.*36C>T | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as rs374938628; called by muse, mutect2
- ZNF335 | c.1355+33A>T | Intron (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
